Somatic mutation profile of tumor specimen TCGA-C5-A1BK-01B (aliquot TCGA-C5-A1BK-01B-11D-A13W-08) from TCGA case TCGA-C5-A1BK, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 36.4 years (13,297 days).
Specimen TCGA-C5-A1BK-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d6808301-fb64-4db9-88f8-9dfcd826e6e2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A1BK-10A (Blood Derived Normal), aliquot TCGA-C5-A1BK-10A-01D-A13W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10b3947b-4e80-4d50-8932-883c7581c907

The open-access MAF lists 183 somatic variants for this specimen: 134 protein-altering or splice-affecting, 46 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 115, Silent 46, Nonsense Mutation 14, Splice Site 3, Intron 2, Frame Shift Del 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STXBP1 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs794727970, CM162470, COSV64812069, COSV64812922; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- VPS53 | c.1516C>T p.R506* (on ENST00000571805 / NM_001366253.2; = p.R477* on NM_018289.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 20/92 reads (22%) | catalogued as rs200594402, CM164762, COSV52126085; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACBD4 | c.237G>A p.M79I | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as rs958462906, COSV58850677; called by muse, mutect2, varscan2
- ACTN3 | c.1730G>A p.R577Q | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.066); catalogued as rs781859126, COSV100074372; called by muse, mutect2, varscan2
- ADAMTS19 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.832); catalogued as COSV50731954; called by muse, mutect2, varscan2
- ADAMTS3 | c.755G>C p.G252A | Missense Mutation (SNP) | VAF 54/284 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0.013); catalogued as COSV54384535, COSV54387924; called by muse, mutect2, varscan2
- ADGRF5 | c.2221C>G p.Q741E | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.67); PolyPhen benign (0.139); catalogued as COSV51929680, COSV99344860; called by muse, mutect2, varscan2
- ALOX15B | c.882C>G p.I294M | Missense Mutation (SNP) | VAF 40/180 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.491); catalogued as COSV66478949; called by muse, mutect2, varscan2
- ARHGAP6 | c.2278G>A p.E760K (on ENST00000337414 / NM_013427.3; = p.E557K on NM_013423.3) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as COSV57290834; called by muse, mutect2, varscan2
- ARMC1 | c.372G>A p.M124I | Missense Mutation (SNP) | VAF 46/188 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as COSV52533002; called by muse, mutect2, varscan2
- BABAM2 | c.1069G>C p.E357Q | Missense Mutation (SNP) | VAF 40/186 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV59616856; called by muse, mutect2, varscan2
- BMPR2 | c.2618G>A p.R873Q | Missense Mutation (SNP) | VAF 49/176 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.205); catalogued as rs201781338, CM085277, COSV65813690; ClinVar: likely benign; called by muse, mutect2, varscan2
- BTBD11 | c.2442C>G p.I814M (on ENST00000280758 / NM_001018072.2; = p.I351M on NM_001017523.2) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs778909631, COSV55016821, COSV55032919; called by muse, mutect2, varscan2
- C2orf16 | c.3115G>A p.D1039N | Missense Mutation (SNP) | VAF 35/196 reads (18%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs754428308, COSV62673723; called by muse, mutect2, varscan2
- CALM1 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.574); catalogued as COSV63662615; called by muse, mutect2, varscan2
- CAMK2N2 | c.157C>T p.R53* | Nonsense Mutation (SNP) | VAF 5/32 reads (16%) | catalogued as COSV56181562; called by muse, mutect2
- CATSPERD | c.218del p.F73Sfs*26 | Frame Shift Del (DEL) | VAF 39/221 reads (18%) | catalogued as rs1305833783; called by mutect2, pindel, varscan2
- CD22 | c.2228C>G p.S743C | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV50049601; called by muse, mutect2, varscan2
- CNTRL | c.4714G>C p.E1572Q | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1446862733, COSV99443013; called by muse, mutect2
- CSF1R | c.916G>C p.E306Q | Missense Mutation (SNP) | VAF 38/183 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.157); catalogued as COSV53828332; called by muse, mutect2, varscan2
- CUBN | c.7160C>T p.S2387F | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100913705, COSV64707694; called by muse, mutect2, varscan2
- DGKI | c.1010C>G p.S337* | Nonsense Mutation (SNP) | VAF 7/61 reads (11%) | catalogued as COSV55936037; called by muse, mutect2, varscan2
- DHX57 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as rs768213847, COSV54882361; called by muse, mutect2, varscan2
- DHX57 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV54882373; called by muse, mutect2, varscan2
- DMBT1 | c.1949C>A p.S650* | Nonsense Mutation (SNP) | VAF 56/327 reads (17%) | catalogued as COSV57534166; called by muse, mutect2, varscan2
- DNAH17 | c.4915G>A p.E1639K | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768586788, COSV67749567; called by muse, mutect2, varscan2
- DNAH5 | c.2191G>A p.V731I | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.052); catalogued as COSV54203683; called by muse, mutect2, varscan2
- DNAJC8 | c.126G>C p.Q42H | Missense Mutation (SNP) | VAF 47/175 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.183); catalogued as COSV55280737; called by muse, mutect2, varscan2
- EDC3 | c.343C>G p.Q115E | Missense Mutation (SNP) | VAF 51/193 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.071); catalogued as COSV59339004; called by muse, mutect2, varscan2
- ELOVL5 | c.59-1G>C p.X20_splice | Splice Site (SNP) | VAF 27/101 reads (27%) | catalogued as COSV58648761; called by muse, mutect2, varscan2
- EPHA4 | c.1900G>A p.E634K | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56026222; called by muse, mutect2, varscan2
- FAM171A1 | c.1642C>T p.L548F | Missense Mutation (SNP) | VAF 59/224 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65313372; called by muse, mutect2, varscan2
- FLNA | c.6844G>A p.E2282K (on ENST00000369850 / NM_001110556.2; = p.E2274K on NM_001456.3) | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.575); catalogued as COSV61037284; called by muse, mutect2, varscan2
- FRMPD4 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 20/241 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.056); catalogued as COSV66214142, COSV66221634; called by muse, mutect2
- GAL | c.142G>T p.V48F | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV55763464, COSV55764567; called by muse, mutect2, varscan2
- GGH | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 28/169 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52649164; called by muse, mutect2, varscan2
- GOT2 | c.469C>G p.L157V | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.029); catalogued as COSV55330622; called by muse, mutect2, varscan2
- HELZ | c.2896G>C p.E966Q | Missense Mutation (SNP) | VAF 47/250 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV62376326; called by muse, mutect2, varscan2
- HK3 | c.1537C>T p.R513* | Nonsense Mutation (SNP) | VAF 9/47 reads (19%) | catalogued as rs573086536, COSV52836822; called by muse, mutect2, varscan2
- IGDCC3 | c.2437G>A p.E813K | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0); catalogued as COSV60076396, COSV60078795; called by muse, mutect2, varscan2
- IGLL5 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.282); catalogued as COSV101138867; called by muse, mutect2, varscan2
- IL13RA2 | c.590G>A p.C197Y | Missense Mutation (SNP) | VAF 22/211 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54563920; called by muse, mutect2, varscan2
- IL1R1 | c.1593G>A p.W531* | Nonsense Mutation (SNP) | VAF 10/54 reads (19%) | catalogued as COSV52104585; called by muse, mutect2, varscan2
- IRAK1 | c.910-1G>A p.X304_splice | Splice Site (SNP) | VAF 48/159 reads (30%) | catalogued as COSV57651805; called by muse, mutect2, varscan2
- KAT6A | c.110C>A p.S37Y | Missense Mutation (SNP) | VAF 77/459 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV55902555; called by muse, mutect2, varscan2
- KAT8 | c.868G>C p.E290Q | Missense Mutation (SNP) | VAF 64/396 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54895024; called by muse, mutect2, varscan2
- KCNQ5 | c.1849G>A p.E617K | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59649061; called by muse, mutect2, varscan2
- KIF4B | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV70527793; called by muse, mutect2, varscan2
- KLHL2 | c.1513G>C p.D505H | Missense Mutation (SNP) | VAF 66/287 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56973402; called by muse, mutect2, varscan2
- KLHL42 | c.882C>G p.F294L | Missense Mutation (SNP) | VAF 72/265 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as COSV67145616; called by muse, mutect2, varscan2
- KMT2E | c.4942C>T p.Q1648* | Nonsense Mutation (SNP) | VAF 22/92 reads (24%) | catalogued as COSV57569458; called by muse, mutect2, varscan2
- KRTAP9-8 | c.96C>G p.C32W | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV54199327; called by muse, mutect2, varscan2
- KSR1 | c.1850G>A p.R617H (on ENST00000644974 / NM_001367810.1; = p.R502H on NM_014238.2) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52028209; called by mutect2, varscan2
- LAMB2 | c.4274G>C p.G1425A | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs141317511, COSV59731620; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LIG4 | c.2465C>T p.S822L | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs141441003; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LPGAT1 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 53/351 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV65351021; called by muse, mutect2, varscan2
- LYPD5 | c.480G>C p.Q160H (on ENST00000377950 / NM_001031749.3; = p.Q117H on NM_182573.2) | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV65020271; called by muse, mutect2
- MAP3K20 | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV64377100; called by muse, mutect2, varscan2
- MXRA5 | c.5439G>C p.Q1813H | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV54223594; called by muse, mutect2, varscan2
- MYEOV | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.049); catalogued as COSV58293436; called by muse, varscan2
- MYH10 | c.4444G>C p.E1482Q | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV52594888; called by muse, mutect2, varscan2
- MYLK3 | c.2026C>T p.P676S | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67362519; called by muse, mutect2, varscan2
- MYOF | c.3433G>A p.V1145I | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs760639207, COSV63700177; called by muse, mutect2, varscan2
- MYSM1 | c.979G>C p.D327H | Missense Mutation (SNP) | VAF 52/261 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV68976926; called by muse, mutect2, varscan2
- NAV1 | c.3112G>A p.E1038K | Missense Mutation (SNP) | VAF 36/210 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs761980110, COSV55213994; called by muse, mutect2, varscan2
- NCOA3 | c.2012C>G p.S671C | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV59065541; called by muse, mutect2, varscan2
- NDC80 | c.232G>C p.E78Q | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV55246813; called by muse, mutect2, varscan2
- NDC80 | c.568G>C p.D190H | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55246820; called by muse, mutect2, varscan2
- NKD1 | c.880C>T p.R294* | Nonsense Mutation (SNP) | VAF 13/84 reads (15%) | catalogued as COSV51689373; called by muse, mutect2, varscan2
- NOMO2 | c.1396-1G>A p.X466_splice | Splice Site (SNP) | VAF 23/262 reads (9%) | catalogued as COSV57915472; called by muse, mutect2, varscan2
- NOS1 | c.4036G>T p.E1346* | Nonsense Mutation (SNP) | VAF 25/236 reads (11%) | catalogued as COSV57606555; called by muse, varscan2
- NR1H4 | c.367C>T p.R123C (on ENST00000551379 / NM_001206993.2; = p.R113C on NM_005123.4) | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769086612, COSV51849327, COSV99499901; called by muse, mutect2, varscan2
- OARD1 | c.263C>T p.S88L | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0.214); catalogued as rs770268622, COSV55107310; called by muse, mutect2, varscan2
- OGN | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as COSV52760211, COSV52760272; called by muse, mutect2, varscan2
- OSGIN2 | c.859G>C p.E287Q | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.832); catalogued as COSV52407067; called by muse, mutect2, varscan2
- PARP14 | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1320111559, COSV72111679; called by muse, varscan2
- PCDHB14 | c.2171G>A p.R724H | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.677); catalogued as rs142658705; called by muse, mutect2, varscan2
- PCDHB2 | c.1384G>A p.V462I | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.251); catalogued as COSV50564080; called by muse, mutect2, varscan2
- PDE4A | c.1495G>A p.E499K (on ENST00000380702 / NM_001111307.2; = p.E260K on NM_006202.3) | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.457); catalogued as COSV53350648; called by muse, mutect2, varscan2
- PDLIM5 | c.151C>G p.L51V | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.078); catalogued as COSV58745080; called by muse, mutect2, varscan2
- PFDN6 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.562); catalogued as COSV65841921; called by muse, mutect2, varscan2
- PHF8 | c.1357G>A p.E453K (on ENST00000357988 / NM_001184896.1; = p.E417K on NM_015107.3) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as COSV57677362; called by muse, mutect2
- PHKG2 | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1440723288, COSV60310938; called by muse, mutect2, varscan2
- PIWIL3 | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 13/170 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.679); catalogued as rs548864243, COSV100177808; called by muse, mutect2
- PKD1 | c.6704C>T p.S2235L | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs775101479, CM1413093, COSV51910570, COSV51912935; called by muse, mutect2, varscan2
- PTPN3 | c.538C>G p.Q180E | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52701872; called by muse, mutect2, varscan2
- PWWP3A | c.308C>T p.S103L (on ENST00000627377; = p.S102L on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/172 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs773907661, COSV60900768; called by muse, mutect2, varscan2
- PWWP3A | c.707C>T p.S236L (on ENST00000627377; = p.S235L on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.073); catalogued as rs1391393945, COSV60900773; called by muse, mutect2, varscan2
- PXDN | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); catalogued as rs763793067, COSV53226642; called by muse, mutect2, varscan2
- RAB14 | c.206G>C p.G69A | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65788084; called by muse, varscan2
- RARB | c.1194G>C p.L398F (on ENST00000383772 / NM_001290216.2; = p.L391F on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51968530; called by muse, mutect2, varscan2
- RHOBTB1 | c.1844G>A p.W615* | Nonsense Mutation (SNP) | VAF 29/126 reads (23%) | catalogued as COSV61957718; called by muse, mutect2, varscan2
- RHOU | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as rs1403932785, COSV64208262; called by muse, mutect2, varscan2
- RIOK2 | c.1556G>A p.R519H | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as COSV51615317; called by muse, mutect2
- RNF126 | c.835G>T p.A279S | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.862); catalogued as COSV51260680; called by muse, mutect2
- RNF19A | c.1586G>A p.R529Q | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.652); catalogued as rs1379398447, COSV61992319; called by muse, mutect2, varscan2
- RPGRIP1 | c.1459C>T p.Q487* | Nonsense Mutation (SNP) | VAF 4/33 reads (12%) | catalogued as COSV52844543, COSV52845472; called by muse, mutect2, varscan2
- RPS2 | c.137G>C p.R46P | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.969); catalogued as COSV99238875, COSV99238904; called by muse, mutect2
- RPS4X | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.12); catalogued as rs1383264759, COSV60181440; called by muse, mutect2, varscan2
- RTRAF | c.430C>T p.Q144* | Nonsense Mutation (SNP) | VAF 31/116 reads (27%) | catalogued as COSV55562147; called by muse, mutect2, varscan2
- RUFY4 | c.1067G>A p.G356E | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs879248643, COSV60245975; called by muse, mutect2, varscan2
- SAMD4A | c.931C>G p.Q311E | Missense Mutation (SNP) | VAF 46/186 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV51876595; called by muse, mutect2, varscan2
- SEPTIN12 | c.210C>G p.F70L | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1326905010, COSV51615491; called by muse, mutect2, varscan2
- SERPING1 | c.659C>T p.S220L | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as COSV53541497; called by muse, mutect2, varscan2
- SH2D3A | c.674C>G p.S225C | Missense Mutation (SNP) | VAF 69/421 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.417); catalogued as rs754330790, COSV55584595, COSV55588888; called by muse, mutect2, varscan2
- SLC26A5 | c.1280C>G p.A427G | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); catalogued as COSV59697971; called by muse, mutect2, varscan2
- SLC49A4 | c.1348C>T p.P450S | Missense Mutation (SNP) | VAF 96/567 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as rs1384340254, COSV53745363; called by muse, mutect2, varscan2
- SOCS6 | c.1382C>A p.S461* | Nonsense Mutation (SNP) | VAF 27/106 reads (25%) | catalogued as COSV67545957; called by muse, mutect2, varscan2
- SPATA7 | c.1658C>G p.S553* | Nonsense Mutation (SNP) | VAF 9/135 reads (7%) | catalogued as COSV50416429, COSV99248173; called by muse, mutect2
- SPEF2 | c.2297C>T p.A766V | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs754396158, COSV61544205; called by muse, mutect2, varscan2
- SUGT1 | c.607G>C p.E203Q (on ENST00000343788 / NM_001130912.3; = p.E171Q on NM_006704.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV59421014, COSV59421048; called by muse, mutect2, varscan2
- SYT1 | c.883C>A p.L295M | Missense Mutation (SNP) | VAF 77/321 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.493); catalogued as COSV54031137; called by muse, mutect2, varscan2
- TDRD1 | c.3337G>C p.D1113H | Missense Mutation (SNP) | VAF 37/194 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV52587374; called by muse, mutect2, varscan2
- TEP1 | c.850G>C p.E284Q | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV52987950, COSV52994893, COSV53000407; called by muse, mutect2, varscan2
- TFCP2 | c.1365C>G p.I455M | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56931252; called by muse, mutect2, varscan2
- TGFB3 | c.114G>C p.K38N | Missense Mutation (SNP) | VAF 22/194 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53168909; called by muse, varscan2
- TIE1 | c.2689C>A p.H897N | Missense Mutation (SNP) | VAF 52/260 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV65248438, COSV65248446; called by muse, mutect2, varscan2
- TIGD4 | c.1493C>T p.S498F | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.483); catalogued as COSV58548975, COSV58549155; called by muse, mutect2, varscan2
- TMEM59 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.026); catalogued as COSV52372627; called by muse, mutect2, varscan2
- TRIM13 | c.936G>T p.W312C | Missense Mutation (SNP) | VAF 84/445 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.43); catalogued as COSV53947963; called by muse, mutect2, varscan2
- TYK2 | c.2554G>A p.E852K | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); catalogued as COSV99315031; called by muse, mutect2
- UBE3C | c.1099G>A p.D367N | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.102); catalogued as COSV100779855, COSV61950993; called by muse, mutect2, varscan2
- UHRF1BP1L | c.2399C>T p.S800L | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.155); catalogued as rs373719344; called by muse, mutect2, varscan2
- UNG | c.487C>T p.H163Y (on ENST00000242576 / NM_080911.3; = p.H154Y on NM_003362.4) | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54356490; called by muse, mutect2, varscan2
- USP29 | c.1645C>T p.L549F | Missense Mutation (SNP) | VAF 81/363 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.113); catalogued as COSV54139866; called by muse, mutect2, varscan2
- USP53 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.759); catalogued as COSV56792204; called by muse, mutect2, varscan2
- WDR83 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as rs1209959604, COSV52951505; called by muse, mutect2, varscan2
- WNK4 | c.2974C>G p.P992A | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV55901439; called by muse, mutect2, varscan2
- YIPF3 | c.237C>G p.F79L | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs150101467, COSV58303479; called by muse, mutect2, varscan2
- YY1 | c.705G>C p.E235D | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV51760955; called by muse, mutect2, varscan2
- ZFP82 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 44/272 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as COSV67564583; called by muse, mutect2, varscan2
- ZIM2 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as rs767848453, COSV55624495, COSV55650701, COSV99686891; called by muse, mutect2, varscan2
- ZNF687 | c.805C>T p.H269Y | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.139); catalogued as COSV55014916; called by muse, mutect2, varscan2
- TMCC1 | c.1840del p.L614Sfs*2 (on ENST00000393238 / NM_001349268.2; = p.L290Sfs*2 on NM_015008.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 22/186 reads (12%) | called by mutect2, pindel, varscan2
- ACTL8 | c.936C>T p.F312= | Silent (SNP) | VAF 28/114 reads (25%) | catalogued as COSV100958720; called by muse, mutect2, varscan2
- APBB1 | c.1932C>T p.A644= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as COSV54966260; called by muse, mutect2, varscan2
- APH1A | c.54C>T p.F18= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs782165938, COSV52528202; called by muse, mutect2, varscan2
- ATF4 | c.258G>A p.L86= | Silent (SNP) | VAF 56/206 reads (27%) | catalogued as COSV57477567; called by muse, mutect2, varscan2
- CASZ1 | c.582G>A p.Q194= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV59731907; called by muse, varscan2
- COL4A5 | c.30C>T p.A10= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV57859161; called by muse, mutect2, varscan2
- CPT1C | c.597C>T p.F199= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV54917507; called by muse, mutect2, varscan2
- CRYBG3 | c.8442G>A p.E2814= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as COSV51709428; called by muse, mutect2, varscan2
- CSMD2 | c.6033G>A p.L2011= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV53878193; called by muse, mutect2, varscan2
- CYP2B6 | c.1371C>T p.F457= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV57842432; called by muse, mutect2, varscan2
- DENND2A | c.1431G>A p.K477= | Silent (SNP) | VAF 59/313 reads (19%) | catalogued as COSV52047475; called by muse, mutect2, varscan2
- DNAH17 | c.5232C>T p.N1744= | Silent (SNP) | VAF 18/118 reads (15%) | catalogued as COSV67749560; called by muse, mutect2, varscan2
- EVI5 | c.1101G>C p.L367= | Silent (SNP) | VAF 23/108 reads (21%) | catalogued as COSV64825482; called by muse, mutect2, varscan2
- EXOC8 | c.888G>A p.A296= | Silent (SNP) | VAF 30/159 reads (19%) | catalogued as rs1174976436, COSV50477525; called by muse, mutect2, varscan2
- GEMIN5 | c.3639G>A p.L1213= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV53557949; called by muse, mutect2, varscan2
- GPATCH8 | c.4173C>T p.I1391= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs774461978, COSV59193138, COSV59198588; called by muse, mutect2, varscan2
- HIPK4 | c.477C>T p.F159= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as rs745473915, COSV52519032; called by muse, mutect2, varscan2
- HSP90AB1 | c.954C>T p.V318= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as COSV62333167; called by muse, mutect2, varscan2
- MCHR2 | c.921C>T p.I307= | Silent (SNP) | VAF 32/218 reads (15%) | catalogued as COSV55999448; called by muse, mutect2, varscan2
- MORC3 | c.1731C>T p.V577= | Silent (SNP) | VAF 37/157 reads (24%) | catalogued as COSV68687717; called by muse, mutect2, varscan2
- MORC3 | c.2172C>T p.I724= | Silent (SNP) | VAF 23/146 reads (16%) | catalogued as COSV68687721; called by muse, mutect2, varscan2
- MUC17 | c.1200C>T p.V400= | Silent (SNP) | VAF 68/338 reads (20%) | catalogued as COSV60279755, COSV60296183; called by muse, mutect2, varscan2
- NALCN | c.420C>A p.G140= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV51917166; called by muse, mutect2, varscan2
- PARP9 | c.1866G>A p.S622= | Silent (SNP) | VAF 15/106 reads (14%) | catalogued as rs376768463; called by muse, mutect2, varscan2
- PCBP3 | c.702C>A p.A234= | Silent (SNP) | VAF 11/83 reads (13%) | catalogued as COSV68406518; called by muse, mutect2, varscan2
- PCDHA10 | c.1221G>A p.V407= | Silent (SNP) | VAF 31/205 reads (15%) | catalogued as COSV56477192; called by muse, mutect2, varscan2
- PITPNM2 | c.486C>T p.F162= | Silent (SNP) | VAF 34/208 reads (16%) | catalogued as COSV54895855; called by muse, varscan2
- PLXDC2 | c.960G>T p.V320= | Silent (SNP) | VAF 13/116 reads (11%) | catalogued as COSV65900697, COSV65901125; called by muse, mutect2, varscan2
- PRKCSH | c.687C>A p.V229= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs1336555294, COSV52950258; called by muse, mutect2, varscan2
- PROKR2 | c.234C>T p.L78= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as COSV54085197; called by muse, mutect2, varscan2
- REXO5 | c.2214C>G p.L738= | Silent (SNP) | VAF 37/137 reads (27%) | catalogued as COSV54470674; called by muse, mutect2, varscan2
- RNF6 | c.1461C>T p.I487= | Silent (SNP) | VAF 30/133 reads (23%) | catalogued as COSV60417821; called by muse, mutect2, varscan2
- SEMA3D | c.1278G>A p.V426= | Silent (SNP) | VAF 29/147 reads (20%) | catalogued as rs199899518, COSV52391893; ClinVar: likely benign; called by muse, mutect2, varscan2
- SH3GL1 | c.981C>T p.F327= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV53655775; called by muse, mutect2, varscan2
- SLC5A11 | c.732G>C p.R244= | Silent (SNP) | VAF 35/211 reads (17%) | catalogued as rs780382701, COSV61739963; called by muse, mutect2, varscan2
- TBC1D9 | c.2517C>G p.L839= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as COSV71306829; called by muse, mutect2, varscan2
- TCOF1 | c.2016G>A p.A672= (on ENST00000377797 / NM_001135243.1; = p.A595= on NM_000356.4) | Silent (SNP) | VAF 77/287 reads (27%) | catalogued as rs372688212, COSV60345481; called by muse, mutect2, varscan2
- TIMP4 | c.261C>G p.V87= | Silent (SNP) | VAF 26/113 reads (23%) | catalogued as rs370491983; called by muse, mutect2, varscan2
- TLL2 | c.2808G>A p.R936= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV63570681; called by muse, mutect2, varscan2
- TMEM80 | c.402C>T p.L134= (on ENST00000526170 / NM_001276274.1; = p.L196= on NM_174940.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs560710224, COSV59346748; called by muse, mutect2, varscan2
- TNS4 | c.528C>T p.F176= | Silent (SNP) | VAF 23/105 reads (22%) | catalogued as rs758045618, COSV54183351; called by muse, mutect2, varscan2
- TYROBP | c.282C>G p.L94= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV52887161, COSV52887204; called by muse, mutect2
- UBE2Q1 | c.477C>T p.L159= | Silent (SNP) | VAF 33/205 reads (16%) | catalogued as rs371981564, COSV52723827; called by muse, mutect2, varscan2
- USP3 | c.1503G>A p.A501= | Silent (SNP) | VAF 47/237 reads (20%) | catalogued as rs200782618, COSV51428222; called by muse, mutect2, varscan2
- WDR1 | c.1212G>T p.V404= (on ENST00000382452; = p.V264= on NM_005112.5) | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV66723174; called by muse, mutect2, varscan2
- ZFHX4 | c.4302C>T p.F1434= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV50491183; called by muse, mutect2, varscan2
- OBSCN | c.11659+4340C>T | Intron (SNP) | VAF 19/80 reads (24%) | catalogued as COSV99477204, COSV99481621; called by muse, mutect2, varscan2
- PUS7L | c.-2G>T | 5'UTR (SNP) | VAF 6/48 reads (13%) | catalogued as COSV100786571; called by muse, mutect2, varscan2
- ZGRF1 | c.3127+61G>C | Intron (SNP) | VAF 4/56 reads (7%) | catalogued as COSV100480759, COSV100481172; called by muse, mutect2
